Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE1, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE1-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh, previously-opened status

Operation: Partial hepatectomy

Organs: Liver (9.0 x 9.0 x 3.7 cm, 126.5 gm)

Lesion: A well-defined multinodular golden yellow solid mass (3.5 x 2.4 x 2.0 cm)

Gross type:

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 1.3 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Cirrhotic

Representative sections submitted

Gross photo: Present

Blocks

T1-4, TB, mass x 5

L, NB, liver parenchyma x 2

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation III

The major differentiation III

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Partial capsule

Capsular infiltration: No

Septum formation: No

Surgical resection margin invasion: No, safety margin (1.3 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

liver,ectomy,Hepatocellular carcinoma,cirrhosis,steatosis
T56000, P10, M81703, M49500, M50080

ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
Qx 5/20/14

[page 2 of 2]
DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma, moderately differentiated

Cirrhosis

Steatosis, mild

Suggestion :

Source: NCI Genomic Data Commons file 342e590b-f829-475c-8e62-de25bd55a6c2 (TCGA-DD-AAE1.5357FFD7-B4B7-49A5-A2E3-FE9751DF6A30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).